RC case RC-B65D — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2de0594c-5702-4202-adc9-ae2e948335ef

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1947; Vital status: Dead; Days to death: 334 days; Year of death: 2016.

Diagnoses (5)
1. Prolymphocytic leukemia, T-cell type (the primary disease): ICD-O-3 morphology code: 9834/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 69.0 years (25,186 days); Year of diagnosis: 2016; Method of diagnosis: Blood Draw; Ann Arbor B symptoms: No; Prior malignancy: yes; Synchronous malignancy: Yes; Prior treatment: Yes; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High Risk; Sites of involvement: Bone marrow / Peripheral blood.
   Pathology details: Bone marrow malignant cells: Yes; Timepoint category: Initial Diagnosis.
   Recorded as not given: Organ Transplantation; adjuvant Pharmaceutical Therapy, NOS, postoperative; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, NOS.
2. Synchronous primary of the uterus (histology not recorded by GDC). Age at diagnosis: 68.8 years (25,138 days); Year of diagnosis: 2015; Days to diagnosis: -48 days; AJCC staging edition: 7th; AJCC pathologic stage: Stage III.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -14 days; Treatment anatomic sites: Cervix / Uterus.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 21 days; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 58 days; Treatment anatomic sites: Body, total.
3. Prior malignancy of the skin of other and unspecified parts of face (histology not recorded by GDC). Age at diagnosis: 68.8 years (25,144 days); Year of diagnosis: 2015; Days to diagnosis: -42 days.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -41 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Prior malignancy of the skin of other and unspecified parts of face (histology not recorded by GDC). Laterality: Left.
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
5. Prior malignancy of the skin of other and unspecified parts of face (histology not recorded by GDC).
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 100.
- Day 334 (end of treatment course 1): Disease response: With Tumor.

Molecular and laboratory tests
- Epstein-Barr Virus: Negative [Test analyte type: DNA].
- Lactate Dehydrogenase 374 U/L [Blood test normal range upper: 250].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 99.3 kg; Height: 161 cm; BMI: 38.3.
- Timepoint category: Prior to Diagnosis; Comorbidities: Diabetes, NOS / Hyperlipidemia / Hypertension.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample RC-B65D-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B65D-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
